Surgical pathology report (de-identified scan), TCGA case TCGA-DH-5141, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site University of Florida, specimen TCGA-DH-5141-01A (Primary Tumor).

[page 1 of 2]
Surgical Pathology Consultation / Department of Pathology

TCGA-DH-5141

Case Type: [REDACTED]

[REDACTED]

CLINICAL HISTORY: [REDACTED] gentleman with rhinorrhea in [REDACTED] MRI revealed tumor, which pathology revealed oligodendroglioma. Had left-sided stroke (illegible) month postop. Began having headaches recently and had MRI done revealing a right frontal lesion.

GROSS DESCRIPTION:

Received the following specimens in the Department of Pathology, labeled with the patient's name and [REDACTED]

- A. "Tumor"
- B. "Tumor"
- C. "Tumor"

A. The specimen is received without fixative and consists of two pieces of beige to gray-tan soft tissue, that measure 0.6 x 0.3 x 0.2 cm and 0.5 x 0.3 x 0.2 cm, respectively. A portion of the specimen is submitted for frozen section; the frozen section diagnosis is "Infiltrating glioma, oligodendroglioma not excluded; grade deferred to permanents," per [REDACTED]

[REDACTED] The frozen tissue is resubmitted in FSA1, and the remaining tissue is submitted in A2, for permanent processing. [REDACTED]

B. The specimen is received unfixed and consists of a 32.5 gm portion of apparent cerebral cortex and underlying subcortical white matter, measuring 3.5 x 5.0 x 2.8 cm, with a 1.8 x 1.5 cm ragged, hemorrhagic component. Deep surfaces appear cauterized. Sections reveal effacement of the gray-white junction, especially adjacent to the ragged hemorrhagic region, and a pale tan-yellow tan discoloration of the subcortical tissue. Representative sections are submitted in B1-B6, for permanent processing.

C. The specimen is received unfixed and consists of an 8.0 gm portion of apparent cerebral cortex and underlying subcortical white matter, measuring 4.2 x 3.5 x 1.4 cm. Sections reveal a better-defined gray-white junction and minimal tan discoloration in white matter. Representative sections are submitted in C1-C4, for permanent processing.

DIAGNOSIS:

A. "Tumor", biopsy: Oligodendroglioma, with anaplastic foci (see comment).

B. "Tumor", excision: Oligodendroglioma, with anaplastic foci (see comment).

C. "Tumor", excision: Oligodendroglioma, with anaplastic foci (see comment).

Comment: This infiltrating oligodendroglioma appears to have caused a "vacuolar" degeneration in large areas of involved white matter (GFAP-immunoperoxidase), and has diffusely infiltrated overlying cortex. Perhaps of greater concern, however, are deeper areas with increased cellular density and nuclear atypia, in which Ki-67-immunostain focally labels up to 20% of nuclei, apparently representing areas of anaplastic "transformation".

[page 2 of 2]
"I, or my qualified designee, have performed the gross examination and description and I have personally reviewed the gross description and specimen preparations referenced herein, and have personally issued this report."

Resident/Prosector/Pathologist: [REDACTED]

Note: Test systems have been developed and their performance characteristics determined by [REDACTED]. Some tests have not been cleared or approved by the U.S. Food and Drug Administration. The FDA has determined that such clearance is not necessary. These tests are used for clinical purposes and should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of [REDACTED] as qualified to perform high complexity clinical laboratory testing.

[REDACTED]
Pathologist

Electronically signed [REDACTED]

ADDENDUM:

FLUORESCENCE IN SITU HYBRIDIZATION (FISH) WAS PERFORMED ON REPRESENTATIVE PARAFFIN-EMBEDDED TUMOR TISSUE (VYSIS). IN THIS CASE, DELETIONS OF BOTH 1P AND 19Q WERE IDENTIFIED. RECENT CLINICAL STUDIES HAVE SUGGESTED THAT COMBINED LOSS OF CHROMOSOME 1P AND 19Q IN OLIGODENDROGLIAL BRAIN TUMORS MAY BE ASSOCIATED WITH PROLONGED SURVIVAL AND ENHANCED RESPONSE TO CHEMOTHERAPY (REFS 1-5).

[REDACTED]
REFERENCES:

[REDACTED]
Pathologist

Electronically signed [REDACTED]

Source: NCI Genomic Data Commons file f131e655-fb6c-423a-94f7-b6ff0bd5737b (TCGA-DH-5141.15A0F3EC-2BDC-4FB9-AE65-E1C38277FF11.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).